Gene-level copy-number profile of tumor specimen C3L-04014-02 from CPTAC case C3L-04014, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 57.6 years (21,035 days).
Specimen C3L-04014-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d142fecd-5809-4e1f-86be-a763234015e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04014-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/0acbee3e-c103-48ee-98a9-72e6fc72a357

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 6,273; copy number 2: 26,612; copy number 3: 13,626; copy number 4: 10,028; copy number 5: 974; copy number 6: 1,287; copy number 7: 33; copy number 8: 15; copy number 9: 8; copy number 18: 5; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 41 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–2): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr4:119,405,523–119,454,638, 1 gene (within-gene range 0–2): GTF2IP12.
- chr4:119,434,005–119,434,108, 1 gene: RNU6-1217P.
- chr4:119,456,350–119,457,277, 1 gene (within-gene range 0–2): AC093752.2.
- chr10:34,675,635–34,676,041, 1 gene (within-gene range 0–2): RPS12P16.
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,320 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:173,141,100–178,921,841, 93 genes, copy number 5 (broad region; genes not listed).
- chr1:242,082,986–242,524,697, 1 gene, copy number 5 (within-gene range 4–5): PLD5.
- chr1:242,345,558–244,451,909, 36 genes, copy number 5: AL360271.2, RPL10AP5, AL360271.1, AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, C1orf100, AL645465.1, TGIF2P1, ADSS2.
- chr2:94,575,976–95,184,317, 30 genes, copy number 5: AL845331.2, AL845331.1, CNN2P11, GXYLT1P7, CNN2P8, AC073464.2, CYP4F32P, AC073464.1, SNX18P14, ANKRD20A8P, RNU6-1320P, SOWAHCP5, AC097374.1, TEKT4, MTCO1P48, MTCO3P45, RPS24P6, AC103563.3, AC103563.4, AC103563.5, AC103563.1, AC103563.6, AC103563.8, RN7SL575P, AC103563.7, MAL, AC103563.2, MRPS5, ZNF514, ZNF2.
- chr2:176,989,418–177,618,742, 23 genes, copy number 7: AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A.
- chr3:93,843,764–95,683,193, 16 genes, copy number 5: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1.
- chr3:151,425,384–152,151,724, 13 genes, copy number 8 (within-gene range 3–8): IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1.
- chr3:155,240,919–198,123,232, 750 genes, copy number 5–6 (broad region; genes not listed).
- chr4:3,758,748–7,939,926, 78 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr4:49,486,926–49,589,529, 12 genes, copy number 6: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:58,198–1,006,623, 38 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2.
- chr5:28,213,359–28,287,807, 2 genes, copy number 8: AC093300.1, LINC02103.
- chr6:29,722,775–33,009,591, 287 genes, copy number 5 (broad region; genes not listed).
- chr6:62,460,940–62,611,327, 3 genes, copy number 6: DHFRP5, AL355375.1, AL355375.2.
- chr9:23,500,691–26,644,595, 17 genes, copy number 7–18: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1.
- chr9:64,621,560–64,765,535, 4 genes, copy number 5–24: AQP7P2, AL445665.1, AL359955.2, IGKV1OR-2.
- chr12:43,835,967–44,389,762, 4 genes, copy number 5: TMEM117, ZNF75BP, AC025030.2, AC025030.1.
- chr14:18,601,045–18,637,421, 6 genes, copy number 7: OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr14:21,924,063–22,526,906, 96 genes, copy number 5 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 5: TRAC.
- chr16:55,259,969–55,706,192, 14 genes, copy number 5 (within-gene range 3–5): AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2.
- chr20:87,250–26,251,546, 531 genes, copy number 6 (broad region; genes not listed).
- chr20:43,558,968–51,802,521, 236 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:18,857,779–18,967,058, 4 genes, copy number 5: PPIAP22, AL157359.3, AL157359.2, AL157359.1.
- chr22:45,502,238–46,243,756, 25 genes, copy number 5: FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1.

Autosomal genes at a single copy (total copy number 1): 6,273. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
